FM case AD5188 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri.
https://portal.gdc.cancer.gov/cases/48b87250-a8ba-4994-bc66-3d46e86af28a

Female, 42.5 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the cervix uteri; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
